Somatic mutation profile of tumor specimen TCGA-A2-A0ET-01A (aliquot TCGA-A2-A0ET-01A-31D-A045-09) from TCGA case TCGA-A2-A0ET, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 58.8 years (21,464 days).
Specimen TCGA-A2-A0ET-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37d54dff-c731-4d3f-9102-20754db0732d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0ET-10A (Blood Derived Normal), aliquot TCGA-A2-A0ET-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a44410c4-8d3b-4c28-8983-7d0a4df02247

The open-access MAF lists 49 somatic variants for this specimen: 36 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 12, Nonsense Mutation 4, Frame Shift Ins 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT3 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs772090769, COSV55634532; called by muse, mutect2
- ARFGEF1 | c.2723G>A p.R908K | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.241); catalogued as COSV51604942, COSV99144913; called by muse, mutect2
- ATP1A3 | c.3022C>T p.R1008C (on ENST00000545399 / NM_001256214.2; = p.R995C on NM_152296.5) | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57485526, COSV57486287; called by muse, mutect2, varscan2
- CD44 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs989971374, COSV53533293; called by muse, mutect2
- CDADC1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 5/118 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1336484810, COSV51913981, COSV99212615; called by muse, mutect2
- CSMD3 | c.6064T>G p.S2022A (on ENST00000297405 / NM_001363185.1; = p.S1918A on NM_052900.3) | Missense Mutation (SNP) | VAF 7/250 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99848412; called by muse, mutect2
- DHRS2 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 40/70 reads (57%) | catalogued as COSV51630682; called by muse, mutect2, varscan2
- DNM3 | c.2566C>T p.R856C (on ENST00000355305 / NM_001350206.2; = p.R850C on NM_015569.5) | Missense Mutation (SNP) | VAF 122/1026 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1408722577, COSV62453819, COSV62463620; called by muse, mutect2, varscan2
- DPYS | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1380835122, COSV100679742, COSV60906734; called by muse, mutect2, varscan2
- DSPP | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 44/553 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.553); catalogued as COSV56817823; called by muse, mutect2
- EFCAB13 | c.2792C>T p.S931L | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.024); catalogued as rs369709542, COSV58946115; called by muse, mutect2
- FBXO30 | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766036145, COSV52790339; called by muse, mutect2, varscan2
- GAREM1 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52506425; called by muse, mutect2, varscan2
- GBP4 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771688858, COSV63253130; called by muse, mutect2, varscan2
- GPR182 | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 132/213 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs969508465, COSV55625581; called by muse, mutect2, varscan2
- IGLV1-47 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs556936347; called by muse, mutect2, varscan2
- IQGAP2 | c.2846C>A p.S949* | Nonsense Mutation (SNP) | VAF 19/160 reads (12%) | catalogued as COSV57168766; called by muse, mutect2, varscan2
- IWS1 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 554/678 reads (82%) | catalogued as COSV54866814; called by muse, mutect2, varscan2
- LDB2 | c.8G>T p.S3I | Missense Mutation (SNP) | VAF 42/504 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); catalogued as COSV100454902; called by muse, mutect2
- LIPE | c.392T>G p.L131W | Missense Mutation (SNP) | VAF 148/376 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV54921588, COSV99734110; called by muse, mutect2, varscan2
- LPA | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as COSV100308119; called by muse, mutect2
- LTN1 | c.3841G>A p.A1281T | Missense Mutation (SNP) | VAF 60/98 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0.122); catalogued as COSV63733107; called by muse, mutect2, varscan2
- NRIP1 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100013132; called by muse, mutect2, varscan2
- OR51A4 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as rs770854830, COSV66749129; called by muse, mutect2, varscan2
- PYCR2 | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs538606802, COSV59524584; called by muse, mutect2, varscan2
- RAPGEF3 | c.2188C>A p.P730T (on ENST00000389212; = p.P688T on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV99406902; called by mutect2, varscan2
- RASGRP2 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1326711154, COSV100818361, COSV62448736; called by muse, mutect2
- SPTA1 | c.1055G>T p.W352L | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100933963; called by muse, mutect2
- TLN1 | c.3721C>T p.R1241W | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs770655381, COSV59209675; called by muse, mutect2, varscan2
- TMEM132B | c.3168C>A p.C1056* | Nonsense Mutation (SNP) | VAF 57/82 reads (70%) | catalogued as COSV54746197; called by muse, mutect2, varscan2
- TMEM161A | c.570G>T p.E190D | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV50776227; called by muse, mutect2, varscan2
- UHRF1BP1 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs757764368, COSV51953074; called by muse, mutect2, varscan2
- UST | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs370216214; called by muse, mutect2, varscan2
- ZFP90 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 138/275 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV68050684; called by muse, mutect2, varscan2
- FANCB | c.1252dup p.I418Nfs*18 | Frame Shift Ins (INS) | VAF 47/196 reads (24%) | called by mutect2, pindel, varscan2
- MYB | c.283dup p.W95Lfs*37 | Frame Shift Ins (INS) | VAF 71/120 reads (59%) | called by mutect2, pindel, varscan2
- APOB | c.393C>T p.L131= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV51925339; called by muse, mutect2, varscan2
- CACNA1H | c.6849C>T p.D2283= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as rs369051137; called by muse, mutect2, varscan2
- CTTNBP2 | c.3183G>A p.P1061= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs747361472, COSV50390675; called by muse, mutect2, varscan2
- FAT4 | c.14049T>C p.G4683= | Silent (SNP) | VAF 27/268 reads (10%) | catalogued as COSV100630276, COSV58677683; called by muse, mutect2
- FCRL3 | c.252C>A p.T84= | Silent (SNP) | VAF 29/696 reads (4%) | catalogued as COSV100943567; called by muse, mutect2
- FSCB | c.2343A>G p.E781= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV61216803; called by muse, mutect2, varscan2
- NAA25 | c.765C>G p.L255= | Silent (SNP) | VAF 38/269 reads (14%) | catalogued as rs1394085961, COSV55702541; called by muse, mutect2, varscan2
- NTN4 | c.1515A>G p.K505= | Silent (SNP) | VAF 163/238 reads (68%) | catalogued as COSV59217635; called by muse, mutect2, varscan2
- PMVK | c.123C>T p.L41= | Silent (SNP) | VAF 73/312 reads (23%) | catalogued as COSV63785632; called by muse, mutect2, varscan2
- TBX5 | c.174C>T p.L58= | Silent (SNP) | VAF 36/522 reads (7%) | catalogued as rs886048998, COSV100092219; ClinVar: uncertain significance; called by muse, mutect2
- TMEM91 | c.237G>A p.S79= | Silent (SNP) | VAF 31/445 reads (7%) | catalogued as rs1453764880, COSV99652765; called by muse, mutect2
- TRIO | c.8502C>T p.R2834= | Silent (SNP) | VAF 31/135 reads (23%) | catalogued as rs760721624, COSV59988867, COSV59992721; called by muse, mutect2, varscan2
- OR2W5 | n.491T>A | RNA (SNP) | VAF 42/335 reads (13%) | called by muse, mutect2, varscan2
